Somatic mutation profile of tumor specimen TCGA-26-6174-01A (aliquot TCGA-26-6174-01A-21D-1845-08) from TCGA case TCGA-26-6174, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 65.4 years (23,884 days).
Specimen TCGA-26-6174-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff9edeaf-045d-4c5b-948d-27d4fdab65f3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-26-6174-10A (Blood Derived Normal), aliquot TCGA-26-6174-10A-01D-1845-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b1e9ee87-fe9c-4e8c-8e45-3dbbb4b2e0d8

The open-access MAF lists 89 somatic variants for this specimen: 74 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 69, Silent 13, Nonsense Mutation 3, Frame Shift Ins 1, Intron 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.533A>G p.Y178C | Missense Mutation (SNP) | VAF 66/140 reads (47%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs786204866, COSV64295911, COSV64300168, COSV64307472; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCA6 | c.4506C>G p.N1502K | Missense Mutation (SNP) | VAF 28/314 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as COSV52634969, COSV52638053; called by muse, mutect2
- ADAMTS2 | c.1607G>A p.G536E | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51076517; called by mutect2, varscan2
- ALOX15B | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as rs375708086, COSV66479103; called by muse, mutect2, varscan2
- ANO4 | c.2126T>C p.L709P (on ENST00000392977 / NM_001286615.2; = p.L674P on NM_178826.4) | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54594118; called by mutect2, varscan2
- APLP2 | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as COSV53840547; called by muse, mutect2
- ARFGEF3 | c.4452G>C p.L1484F | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52456282; called by muse, mutect2, varscan2
- ARHGEF6 | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51689973; called by muse, mutect2, varscan2
- ATG2B | c.3766A>G p.I1256V | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55890185; called by muse, mutect2, varscan2
- AXDND1 | c.1436A>C p.E479A | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as COSV62642043; called by muse, mutect2, varscan2
- BRCA2 | c.5254C>A p.H1752N | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.353); catalogued as CD044123, COSV101203843, COSV66452903; called by muse, mutect2, varscan2
- CDKL2 | c.1121A>G p.N374S | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as COSV56733317; called by muse, mutect2, varscan2
- CHD8 | c.1111C>G p.Q371E (on ENST00000646647 / NM_001170629.2; = p.Q92E on NM_020920.4) | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.003); catalogued as COSV67870377; called by muse, mutect2, varscan2
- CHM | c.1317T>A p.F439L | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV63003556; called by muse, mutect2
- CLASRP | c.490G>A p.G164S | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0.03); catalogued as rs1181802908, COSV55515060; called by muse, varscan2
- CLVS2 | c.359T>C p.V120A | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.428); catalogued as COSV51561489; called by muse, mutect2, varscan2
- COL11A2 | c.4951G>T p.V1651F (on ENST00000341947 / NM_080680.3; = p.V1544F on NM_080679.2) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV59496404; called by muse, mutect2, varscan2
- CPNE4 | c.1446G>A p.M482I | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV70193672; called by muse, mutect2, varscan2
- CPT1A | c.1459T>G p.Y487D | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.371); catalogued as rs985269276, COSV99680894; called by muse, mutect2, varscan2
- CRP | c.309G>T p.E103D | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1461376236, COSV54813361; called by muse, mutect2, varscan2
- CTNNA3 | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 48/111 reads (43%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as rs139378888; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTTN | c.712G>A p.V238M | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs567039880, COSV57231996, COSV57234724; called by muse, mutect2, varscan2
- DDX60L | c.5024G>A p.R1675H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs771464614, COSV52712546, COSV52723736; called by muse, mutect2, varscan2
- DKC1 | c.1142G>C p.G381A | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV65777377; called by muse, mutect2, varscan2
- DYNC1I1 | c.1366G>A p.V456M | Missense Mutation (SNP) | VAF 36/223 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as rs1227595850, COSV61459934; called by muse, mutect2, varscan2
- EHD3 | c.883A>G p.N295D | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as COSV59030271; called by muse, mutect2, varscan2
- EPHA3 | c.204C>G p.Y68* | Nonsense Mutation (SNP) | VAF 17/70 reads (24%) | catalogued as COSV60703506; called by muse, mutect2, varscan2
- EPHB2 | c.568G>A p.V190M | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757529004, COSV65862198; called by muse, mutect2, varscan2
- ERN2 | c.1270T>C p.S424P | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.112); catalogued as COSV56833317; called by muse, mutect2, varscan2
- EYS | c.1211A>T p.N404I | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.109); catalogued as COSV60983768; called by muse, mutect2, varscan2
- FER1L6 | c.1184G>A p.G395D | Missense Mutation (SNP) | VAF 47/213 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs756831243, COSV67549622; called by muse, mutect2, varscan2
- GRHL2 | c.802A>T p.T268S | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.31); catalogued as COSV52547869; called by muse, mutect2, varscan2
- IFIT2 | c.1208A>T p.Q403L | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.3); PolyPhen benign (0.045); catalogued as COSV51078747; called by muse, mutect2, varscan2
- ITGA9 | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.407); catalogued as COSV53239692, COSV53246283; called by muse, mutect2, varscan2
- ITIH2 | c.566G>T p.R189M | Missense Mutation (SNP) | VAF 61/163 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64432935, COSV64433300; called by muse, mutect2, varscan2
- KRT24 | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 53/212 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV52880160; called by muse, mutect2, varscan2
- KRT79 | c.1115T>C p.L372P | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57939781; called by muse, mutect2, varscan2
- LILRA4 | c.13C>G p.L5V | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as COSV52491907; called by muse, varscan2
- LPCAT2 | c.122C>T p.P41L | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs766483361, COSV50895229; called by muse, mutect2, varscan2
- MAN2A2 | c.1324T>C p.Y442H | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64638098; called by muse, mutect2, varscan2
- MAST4 | c.5720C>A p.A1907D (on ENST00000403625 / NM_001164664.2; = p.A1718D on NM_015183.3) | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.481); catalogued as COSV55123351; called by muse, mutect2, varscan2
- MYO10 | c.28C>T p.R10W | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs1219159559, COSV72454112; called by muse, mutect2, varscan2
- NCAPH | c.2110C>A p.Q704K | Missense Mutation (SNP) | VAF 26/211 reads (12%) | SIFT tolerated (0.51); PolyPhen benign (0.268); catalogued as COSV53636204; called by muse, mutect2, varscan2
- NT5E | c.1657C>T p.H553Y | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57628197; called by muse, mutect2, varscan2
- OR4C13 | c.322G>T p.V108F | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.342); catalogued as COSV73648730; called by muse, mutect2, varscan2
- OR4M1 | c.857C>T p.P286L | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs762783313, COSV60061014; called by muse, mutect2, varscan2
- PARP9 | c.1085C>T p.S362L | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs376922210, COSV64450352; called by muse, mutect2, varscan2
- PCDHA3 | c.1468G>C p.V490L | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.957); catalogued as COSV100793480, COSV63540920; called by muse, mutect2, varscan2
- PDILT | c.1257G>C p.K419N | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.055); catalogued as COSV56701561; called by muse, mutect2, varscan2
- PIK3R1 | c.1738T>G p.Y580D (on ENST00000521381 / NM_181523.3; = p.Y310D on NM_181504.4) | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57124929, COSV57131742; called by muse, mutect2, varscan2
- PLXNA4 | c.2713G>A p.V905M | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.657); catalogued as COSV58109477; called by muse, mutect2, varscan2
- PORCN | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.13); catalogued as rs373691543, COSV58226129; called by muse, mutect2, varscan2
- PQBP1 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs782634968, COSV54429592; called by muse, mutect2, varscan2
- PTPRS | c.3362T>G p.L1121R | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as COSV53618256; called by muse, mutect2, varscan2
- RNF17 | c.1400G>A p.G467D | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55039239; called by muse, mutect2, varscan2
- RPL5 | c.48C>A p.Y16* | Nonsense Mutation (SNP) | VAF 17/64 reads (27%) | catalogued as rs148673599, CM086905, CM108638, COSV59873416, COSV59874144; called by muse, mutect2, varscan2
- SCN10A | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 50/171 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.798); catalogued as COSV71861153; called by muse, mutect2, varscan2
- SENP3 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.84); catalogued as rs1291795290, COSV53435778; called by muse, mutect2, varscan2
- SLC12A9 | c.17C>G p.S6* | Nonsense Mutation (SNP) | VAF 13/94 reads (14%) | catalogued as COSV51932443, COSV51932994; called by muse, mutect2, varscan2
- SLC22A18 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.041); catalogued as rs368091563; called by muse, mutect2
- SLC35F4 | c.34C>G p.L12V | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV60264403; called by mutect2, varscan2
- SP3 | c.1754G>A p.G585E | Missense Mutation (SNP) | VAF 46/188 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV59467383; called by muse, mutect2, varscan2
- SP4 | c.1051T>A p.S351T | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.95); PolyPhen benign (0.011); catalogued as COSV56022352; called by muse, mutect2, varscan2
- SPAG17 | c.5876T>C p.F1959S | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV60457795; called by muse, mutect2, varscan2
- TOPORS | c.1056A>G p.I352M | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV62116791; called by muse, mutect2, varscan2
- TTN | c.42253G>T p.V14085F (on ENST00000591111; = p.V6661F on NM_003319.4) | Missense Mutation (SNP) | VAF 45/198 reads (23%) | PolyPhen benign (0.106); catalogued as COSV60017870; called by muse, mutect2, varscan2
- TTN | c.2227G>A p.A743T (on ENST00000591111; = p.A697T on NM_003319.4) | Missense Mutation (SNP) | VAF 14/65 reads (22%) | PolyPhen benign (0.001); catalogued as rs370728359; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- UHMK1 | c.1195G>C p.V399L | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV56419917; called by muse, mutect2, varscan2
- ZMYND19 | c.540+1G>A p.X180_splice | Splice Site (SNP) | VAF 35/165 reads (21%) | catalogued as COSV53021955; called by muse, mutect2, varscan2
- ZNF236 | c.3040G>A p.E1014K | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.837); catalogued as rs776798483, COSV53487107; called by muse, mutect2, varscan2
- ZNF347 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs775039767, COSV61968550; called by muse, mutect2, varscan2
- ZNF99 | c.2021A>G p.E674G | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.44); catalogued as rs753263094, COSV68055607; called by muse, mutect2, varscan2
- MRC1 | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 29/185 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPHP3 | c.2227dup p.D743Gfs*7 | Frame Shift Ins (INS) | VAF 24/128 reads (19%) | called by mutect2, pindel, varscan2
- C16orf46 | c.828C>T p.N276= | Silent (SNP) | VAF 28/262 reads (11%) | catalogued as rs537023465, COSV55150934; called by muse, mutect2
- CT83 | c.297T>G p.L99= | Silent (SNP) | VAF 44/188 reads (23%) | catalogued as COSV64140996; called by muse, mutect2, varscan2
- DDX4 | c.1047T>C p.H349= | Silent (SNP) | VAF 7/101 reads (7%) | catalogued as COSV61754746; called by muse, mutect2
- KHDRBS2 | c.924A>G p.G308= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV55448245; called by muse, mutect2, varscan2
- KIAA0513 | c.1134G>A p.K378= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as COSV50741116; called by muse, mutect2, varscan2
- KIF4B | c.102C>T p.F34= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as rs1457015042, COSV70529082; called by muse, mutect2, varscan2
- OR5H1 | c.828A>G p.L276= | Silent (SNP) | VAF 42/153 reads (27%) | catalogued as rs751264873, COSV100641635, COSV63402303; called by muse, mutect2, varscan2
- PARP8 | c.1257A>G p.E419= | Silent (SNP) | VAF 16/60 reads (27%) | catalogued as COSV55859369; called by muse, mutect2, varscan2
- PCDHA13 | c.2055C>T p.G685= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as COSV56482120; called by muse, mutect2, varscan2
- PTPRU | c.1842G>A p.P614= | Silent (SNP) | VAF 17/78 reads (22%) | catalogued as rs201241001; called by muse, mutect2, varscan2
- REM1 | c.396C>T p.V132= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs147559982; called by muse, mutect2, varscan2
- SYCP1 | c.336G>A p.E112= | Silent (SNP) | VAF 17/91 reads (19%) | catalogued as COSV65696922; called by muse, mutect2, varscan2
- TNFSF11 | c.492T>A p.P164= | Silent (SNP) | VAF 20/113 reads (18%) | catalogued as COSV53477418, COSV99520509; called by muse, mutect2, varscan2
- SPATA8 | n.229C>T | RNA (SNP) | VAF 15/56 reads (27%) | catalogued as rs768208250, COSV100139006, COSV60704579; called by muse, mutect2, varscan2
- TP63 | c.1350-6313T>G | Intron (SNP) | VAF 27/122 reads (22%) | catalogued as COSV53204325, COSV99286370; called by muse, mutect2, varscan2
